Somatic mutation profile of tumor specimen 0DJA08 from CCDI case PBBWTC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,381 days).
Specimen 0DJA08: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cc03e21-1905-4680-a0af-293448debff6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJ9ZW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/808206c8-0091-4999-84e2-8d3dbab04713

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 7, Frame Shift Del 2, In Frame Del 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1820del p.G607Vfs*96 | Frame Shift Del (DEL) | VAF 104/492 reads (21%) | catalogued as COSV100039611, COSV60107237; called by mutect2, pindel, varscan2
- C11orf24 | c.1291_1293del p.K431del | In Frame Del (DEL) | VAF 218/494 reads (44%) | catalogued as rs759054521; called by pindel, varscan2
- DPYD | c.1519G>A p.V507I | Missense Mutation (SNP) | VAF 218/562 reads (39%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs138391898; called by muse, mutect2, varscan2
- H3C3 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 253/550 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV63551114; called by muse, mutect2, varscan2
- PCNX1 | c.3194G>A p.R1065H | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs373015087, COSV53095227; called by muse, mutect2, varscan2
- PLA2G4C | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 335/812 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs776350761; called by muse, mutect2, varscan2
- RING1 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 160/691 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV100761692; called by muse, mutect2, varscan2
- TERB1 | c.2012G>A p.R671H | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs78216962; called by muse, mutect2, varscan2
- CFAP97 | c.759_762del p.D254* | Frame Shift Del (DEL) | VAF 136/705 reads (19%) | called by pindel, varscan2
- CHST2 | c.1501C>T p.Q501* | Nonsense Mutation (SNP) | VAF 42/556 reads (8%) | called by muse, mutect2
- GBX1 | c.260_262del p.F87del | In Frame Del (DEL) | VAF 206/517 reads (40%) | called by mutect2, pindel, varscan2
- NDNF | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 244/577 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- PLCL2 | c.2479G>A p.V827M (on ENST00000615277 / NM_001144382.2; = p.V701M on NM_015184.5) | Missense Mutation (SNP) | VAF 33/453 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); called by muse, mutect2
- USP9Y | c.944T>G p.L315W | Missense Mutation (SNP) | VAF 147/345 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- DNMT1 | c.3381G>A p.P1127= | Silent (SNP) | VAF 83/430 reads (19%) | catalogued as rs756854476; called by muse, mutect2, varscan2
- FOXD4 | c.969G>A p.L323= | Silent (SNP) | VAF 115/877 reads (13%) | catalogued as COSV100070946; called by muse, mutect2, varscan2
- MUC5AC | c.4728C>T p.S1576= | Silent (SNP) | VAF 119/1030 reads (12%) | called by muse, mutect2, varscan2
- MUC5AC | c.5847C>T p.S1949= | Silent (SNP) | VAF 27/202 reads (13%) | called by muse, mutect2, varscan2
- MYH8 | c.4134C>T p.Y1378= | Silent (SNP) | VAF 228/1298 reads (18%) | catalogued as rs200411635; called by muse, mutect2, varscan2
- OR11H12 | c.475C>T p.L159= | Silent (SNP) | VAF 98/554 reads (18%) | catalogued as rs770671775; called by muse, varscan2
- SPSB4 | c.51G>A p.P17= | Silent (SNP) | VAF 66/1000 reads (7%) | catalogued as rs1209973091; called by muse, mutect2
- CFAP20 | c.85-19C>T | Intron (SNP) | VAF 37/190 reads (19%) | catalogued as rs199717197; called by muse, mutect2, varscan2
